Somatic mutation profile of tumor specimen 27f3ca2d-a86f-479d-8e7e-5307c7 (aliquot 27f3ca2d-a86f-479d-8e7e-5307c7_D6) from CPTAC case 02OV022, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen 27f3ca2d-a86f-479d-8e7e-5307c7: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a283e5d-f85b-4228-af93-920e7259e54f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 01de44a7-81fa-4e25-aba5-9b215e (Blood Derived Normal), aliquot 01de44a7-81fa-4e25-aba5-9b215e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ead343b6-c585-4c97-9ff1-1d21e45e2ae6

The open-access MAF lists 111 somatic variants for this specimen: 75 protein-altering or splice-affecting, 19 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Intron 11, Nonsense Mutation 7, 3'UTR 4, Frame Shift Del 4, 5'Flank 2, Splice Region 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP16 | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 58/142 reads (41%) | hotspot (GDC flag); catalogued as COSV53806110; called by muse, mutect2, varscan2
- ANO3 | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV99886001; called by muse, mutect2, varscan2
- APBB3 | c.1399C>T p.R467W (on ENST00000357560 / NM_133173.2; = p.R474W on NM_006051.3) | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs752462282; called by muse, mutect2, varscan2
- ATF7IP2 | c.963C>T p.V321= | Splice Region (SNP) | VAF 15/62 reads (24%) | catalogued as rs755972391; called by muse, mutect2, varscan2
- C1GALT1C1 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV100485642; called by muse, mutect2, varscan2
- CTHRC1 | c.13G>A p.G5S | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1291761462, COSV57715647; called by muse, mutect2, varscan2
- DOCK4 | c.4258C>G p.R1420G | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447821; called by muse, mutect2, varscan2
- FNDC7 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs375047848; called by muse, mutect2, varscan2
- GRB14 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139841108; called by muse, mutect2, varscan2
- HNF1B | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 212/413 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs746992837; called by muse, mutect2, varscan2
- ITPR3 | c.6952A>T p.M2318L | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as rs140741834; called by muse, mutect2, varscan2
- LY9 | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 57/296 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1353333866, COSV54433687; called by muse, mutect2, varscan2
- MAMDC4 | c.1231G>A p.V411I | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as rs751127916, COSV56033187; called by muse, mutect2, varscan2
- MROH1 | c.4047G>A p.L1349= | Splice Region (SNP) | VAF 87/714 reads (12%) | catalogued as rs947102742; called by muse, mutect2, varscan2
- MUC5B | c.10804C>T p.R3602C | Missense Mutation (SNP) | VAF 101/434 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs767890987; called by muse, mutect2, varscan2
- NDUFB9 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 117/621 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754264800; called by muse, mutect2, varscan2
- NDUFV2 | c.634A>G p.K212E | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1210030652; called by muse, mutect2
- NLGN1 | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV64332420; called by muse, mutect2, varscan2
- PDE5A | c.2329C>T p.R777W | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553869290, COSV53347936; called by muse, mutect2, varscan2
- PMPCB | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1473832731; called by muse, mutect2, varscan2
- REPS2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as COSV58179467; called by muse, mutect2, varscan2
- SLC6A5 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 135/450 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV54233640; called by muse, mutect2, varscan2
- TP53 | c.329del p.R110Lfs*13 | Frame Shift Del (DEL) | VAF 37/106 reads (35%) | catalogued as CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; called by mutect2, pindel, varscan2
- TUBA3D | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs746204985; called by muse, mutect2, varscan2
- ZAN | c.6466C>T p.R2156C | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs539457586; called by muse, mutect2, varscan2
- ZBED9 | c.3341A>G p.D1114G | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV101509116; called by muse, mutect2, varscan2
- ZBTB18 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 148/355 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV62397405; called by mutect2, varscan2
- ZNF208 | c.2461A>G p.T821A | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.377); catalogued as rs775648474, COSV101237008; called by muse, mutect2, varscan2
- AMOTL2 | c.1313A>T p.E438V | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ANGPT4 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- ARFGAP2 | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ARHGAP27 | c.1474G>A p.V492M (on ENST00000428638 / NM_001282290.1; = p.V151M on NM_199282.3) | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- CERKL | c.302T>A p.V101E | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRB2 | c.1146_1163del p.C382_T387del | In Frame Del (DEL) | VAF 64/186 reads (34%) | called by mutect2, pindel, varscan2
- CTAGE1 | c.824T>G p.L275* | Nonsense Mutation (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DZIP1L | c.200T>G p.L67W | Missense Mutation (SNP) | VAF 87/397 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L4A | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- EPPK1 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 140/287 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ERP44 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FAM216B | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FGA | c.2450T>C p.L817P | Missense Mutation (SNP) | VAF 74/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR132 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- GRIN3A | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HIC2 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ITGB4 | c.200del p.L67Rfs*94 | Frame Shift Del (DEL) | VAF 122/394 reads (31%) | called by mutect2, pindel, varscan2
- KLRD1 | c.8-1G>T p.X3_splice | Splice Site (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- LRP2 | c.7928T>C p.V2643A | Missense Mutation (SNP) | VAF 100/422 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICALL1 | c.2481G>T p.R827S | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.026); called by mutect2, varscan2
- MLEC | c.170A>C p.E57A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- NUMA1 | c.6336+1G>A p.X2112_splice | Splice Site (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- NUP42 | c.57G>C p.W19C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- PAK5 | c.1669T>C p.S557P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCSK2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, varscan2
- PHACTR4 | c.1198G>A p.D400N (on ENST00000373839 / NM_001350159.2; = p.D410N on NM_023923.4) | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, varscan2
- PLEKHD1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLXNB2 | c.5048G>T p.S1683I | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLA1 | c.437C>G p.T146S | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRLR | c.1651G>C p.G551R | Missense Mutation (SNP) | VAF 90/290 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RESF1 | c.2967_2968del p.N989Kfs*8 | Frame Shift Del (DEL) | VAF 37/206 reads (18%) | called by mutect2, pindel, varscan2
- RNPS1 | c.642_652del p.D214Efs*12 | Frame Shift Del (DEL) | VAF 41/110 reads (37%) | called by mutect2, pindel, varscan2
- SETD5 | c.4234C>T p.Q1412* | Nonsense Mutation (SNP) | VAF 146/475 reads (31%) | called by muse, mutect2, varscan2
- SHROOM2 | c.3889_3892dup p.P1298Lfs*32 | Frame Shift Ins (INS) | VAF 44/154 reads (29%) | called by pindel, varscan2
- SHROOM2 | c.3892_3893insT p.P1298Lfs*31 | Frame Shift Ins (INS) | VAF 57/183 reads (31%) | called by muse*, mutect2, varscan2*
- SLC2A13 | c.1095G>C p.W365C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC45A4 | c.1384C>T p.Q462* (on ENST00000517878 / NM_001286646.2; = p.Q411* on NM_001080431.2) | Nonsense Mutation (SNP) | VAF 28/645 reads (4%) | called by muse, mutect2
- SLC7A14 | c.1060C>A p.L354I | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SLITRK1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.257); called by muse, mutect2
- SMG1 | c.6506T>C p.F2169S | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SYNE2 | c.18390A>C p.K6130N | Missense Mutation (SNP) | VAF 112/397 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TH | c.1558C>A p.L520I (on ENST00000381178 / NM_199292.3; = p.L489I on NM_000360.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TRPC6 | c.1479G>A p.W493* | Nonsense Mutation (SNP) | VAF 140/520 reads (27%) | called by muse, mutect2, varscan2
- UNC45B | c.2364G>T p.M788I | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- UPP1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- USP37 | c.1933G>C p.A645P | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, varscan2
- AKAP6 | c.4380A>G p.G1460= | Silent (SNP) | VAF 55/202 reads (27%) | called by muse, mutect2, varscan2
- AKR1C8P | c.747G>A p.K249= | Silent (SNP) | VAF 38/252 reads (15%) | called by muse, mutect2, varscan2
- C2orf78 | c.12G>A p.L4= | Silent (SNP) | VAF 22/127 reads (17%) | called by muse, mutect2, varscan2
- DSP | c.4023C>A p.R1341= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV65793908; called by muse, mutect2, varscan2
- DUSP10 | c.1284G>A p.R428= | Silent (SNP) | VAF 60/287 reads (21%) | catalogued as rs778427497, COSV60458872; called by muse, mutect2, varscan2
- FEM1A | c.1578C>A p.L526= | Silent (SNP) | VAF 89/343 reads (26%) | called by mutect2, varscan2
- GRM2 | c.39G>T p.L13= | Silent (SNP) | VAF 54/206 reads (26%) | called by mutect2, varscan2
- IGLV9-49 | c.93C>G p.A31= | Silent (SNP) | VAF 51/202 reads (25%) | called by muse, mutect2, varscan2
- ITPR3 | c.4860C>A p.V1620= | Silent (SNP) | VAF 43/244 reads (18%) | called by muse, mutect2, varscan2
- MTCL1 | c.3357G>A p.R1119= (on ENST00000306329 / NM_001378206.1; = p.R800= on NM_015210.4) | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as rs200288992; called by muse, mutect2, varscan2
- MYO7B | c.3225A>T p.A1075= | Silent (SNP) | VAF 58/240 reads (24%) | called by muse, mutect2, varscan2
- NTRK1 | c.855G>A p.P285= | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as rs776087801; called by muse, mutect2, varscan2
- OR2AG2 | c.627C>T p.L209= | Silent (SNP) | VAF 37/479 reads (8%) | called by muse, mutect2
- OR2F1 | c.552G>T p.V184= | Silent (SNP) | VAF 114/336 reads (34%) | called by mutect2, varscan2
- PCBP1 | c.996T>A p.S332= | Silent (SNP) | VAF 56/227 reads (25%) | called by muse, mutect2, varscan2
- RALGAPB | c.4242T>C p.N1414= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV53434329; called by muse, mutect2, varscan2
- SYNPO2L | c.786A>G p.A262= (on ENST00000394810 / NM_001114133.3; = p.A38= on NM_024875.5) | Silent (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- UGGT2 | c.1245C>T p.I415= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV65073252; called by muse, mutect2, varscan2
- ZIC4 | c.864C>T p.H288= | Silent (SNP) | VAF 128/392 reads (33%) | catalogued as rs961981704, COSV67170680, COSV67173427; called by muse, mutect2, varscan2
- ACSF3 | c.*1391G>A | 3'UTR (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- COL24A1 | c.4782+1076A>C | Intron (SNP) | VAF 52/203 reads (26%) | called by muse, mutect2, varscan2
- GNAS | chr20:58889179 C>A | 5'Flank (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- HTN3 | c.73-24T>C | Intron (SNP) | VAF 41/114 reads (36%) | called by muse, mutect2, varscan2
- IMMP1L | c.321+3212C>T | Intron (SNP) | VAF 10/39 reads (26%) | catalogued as rs765252466; called by muse, mutect2, varscan2
- JPT2 | c.*93G>A | 3'UTR (SNP) | VAF 81/377 reads (21%) | called by muse, mutect2, varscan2
- KLC1 | c.1651-8262G>C | Intron (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- LDHB | c.596-43T>A | Intron (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- MCFD2 | c.310-326A>T | Intron (SNP) | VAF 29/117 reads (25%) | called by muse, mutect2, varscan2
- MCFD2 | c.310-327G>T | Intron (SNP) | VAF 32/119 reads (27%) | called by muse, mutect2, varscan2
- MOV10 | c.138-1938T>A | Intron (SNP) | VAF 37/167 reads (22%) | catalogued as rs1299283504; called by muse, mutect2, varscan2
- PVR | c.*10G>T | 3'UTR (SNP) | VAF 40/127 reads (31%) | called by muse, mutect2, varscan2
- SNX6 | c.43-37C>T | Intron (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- THADA | c.2311+92G>T | Intron (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- TRIM74 | chr7:72969741 del CAGAGTCACAGCCAGGAAGGG | 5'Flank (DEL) | VAF 56/261 reads (21%) | called by mutect2, pindel, varscan2
- UNC13C | c.4933+1905T>C | Intron (SNP) | VAF 32/112 reads (29%) | catalogued as rs1294784163; called by muse, mutect2
- WDR97 | c.*3_*14del | 3'UTR (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
